Somatic mutation profile of tumor specimen TCGA-RP-A694-06A (aliquot TCGA-RP-A694-06A-11D-A30X-08) from TCGA case TCGA-RP-A694, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 71.3 years (26,044 days).
Specimen TCGA-RP-A694-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74940d19-7a99-4323-9b8c-07cca52faf3c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RP-A694-10A (Blood Derived Normal), aliquot TCGA-RP-A694-10A-01D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0000e8b4-1361-41b9-b11d-bcd26d4c5ee1

The open-access MAF lists 854 somatic variants for this specimen: 560 protein-altering or splice-affecting, 271 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 508, Silent 271, Nonsense Mutation 33, Intron 11, Splice Site 8, RNA 8, Splice Region 7, Translation Start Site 2, 5'UTR 2, Frame Shift Del 2, 3'UTR 2.

Variants (750 of 854; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913386, CM983988, COSV58683051, COSV58690307, COSV58692178; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CNOT9 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 69/195 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs267599211, COSV55298957; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EBF2 | c.1331G>A p.G444E | Missense Mutation (SNP) | VAF 18/136 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV68776268, COSV68778111; called by muse, mutect2, varscan2
- EXT2 | c.544C>T p.R182* (on ENST00000343631; = p.R215* on NM_000401.3) | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | catalogued as rs886039358, CM000143, COSV59148031; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AATK | c.3319C>T p.P1107S (on ENST00000326724 / NM_001080395.3; = p.P1004S on NM_004920.2) | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs767540180, COSV100352746; called by muse, varscan2
- ABCA12 | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as COSV55971006; called by muse, mutect2, varscan2
- ABCA13 | c.10049C>T p.T3350I | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.041); catalogued as COSV101446918; called by muse, mutect2, varscan2
- ABCA2 | c.4352C>T p.S1451L (on ENST00000614293; = p.S1421L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs764927602, COSV55805085; called by muse, mutect2, varscan2
- ABCB1 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs761584848, COSV55950092; called by muse, mutect2, varscan2
- ABCD4 | c.1429C>T p.P477S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762672388, COSV53993853; called by muse, mutect2
- ABLIM3 | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV58647405; called by muse, mutect2, varscan2
- ACOT11 | c.710C>T p.T237I | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59350287; called by muse, mutect2, varscan2
- ACSL4 | c.517T>A p.Y173N (on ENST00000340800 / NM_022977.2; = p.Y132N on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/76 reads (76%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as COSV61615423; called by muse, mutect2, varscan2
- ACSL5 | c.1240C>T p.R414C (on ENST00000354273; = p.R470C on NM_016234.3) | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs767315343, COSV100634493, COSV61128829; called by muse, mutect2, varscan2
- ACTL9 | c.1034C>T p.S345L | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1478948010, COSV61005532; called by muse, mutect2, varscan2
- ADAM29 | c.1241G>A p.G414E | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63666852; called by muse, mutect2, varscan2
- ADAMTS18 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51401031; called by muse, mutect2, varscan2
- ADAMTS20 | c.5258A>T p.E1753V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67137069; called by muse, mutect2, varscan2
- ADAMTS20 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.43); PolyPhen benign (0.185); catalogued as COSV67137073; called by muse, mutect2, varscan2
- ADAMTS6 | c.1781G>A p.G594E | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66863436; called by muse, mutect2, varscan2
- ADGRL3 | c.3607G>A p.G1203R (on ENST00000506720 / NM_001322402.2; = p.G1135R on NM_015236.6) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.944); catalogued as COSV72231572; called by muse, mutect2, varscan2
- ADGRV1 | c.12617G>A p.G4206E | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV67992763; called by muse, mutect2, varscan2
- ADH1C | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as COSV72463600; called by muse, mutect2, varscan2
- ADRB2 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100019179; called by muse, mutect2, varscan2
- ADRB2 | c.629T>C p.V210A | Missense Mutation (SNP) | VAF 66/189 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as COSV100019182; called by muse, mutect2, varscan2
- AGT | c.1107G>A p.M369I | Missense Mutation (SNP) | VAF 89/206 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1488667537, COSV64185273; called by muse, mutect2
- AHNAK2 | c.13186C>T p.L4396F | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.702); catalogued as COSV60925522; called by muse, varscan2
- AHNAK2 | c.13144C>T p.P4382S | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100317192; called by muse, varscan2
- AIFM3 | c.1070C>T p.S357F | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59002593; called by muse, mutect2, varscan2
- AK8 | c.565C>T p.H189Y | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53754248; called by muse, mutect2, varscan2
- AKAP6 | c.2939C>T p.S980F | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55227461; called by muse, mutect2, varscan2
- ALPK2 | c.2953C>T p.P985S | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as rs1440266458, COSV64494717; called by muse, mutect2, varscan2
- AMER3 | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs774553121, COSV58468223; called by muse, mutect2, varscan2
- ANK2 | c.1670C>T p.S557F | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs759644404, COSV52168242; called by muse, mutect2, varscan2
- ANKK1 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58273709; called by muse, mutect2, varscan2
- ANKRD17 | c.2903C>T p.P968L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as rs759348299, COSV58226050; called by muse, mutect2, varscan2
- ANKRD30A | c.1370C>T p.S457L (on ENST00000611781; = p.S401L on NM_052997.2) | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV64617632; called by muse, mutect2, varscan2
- ANKS4B | c.1006G>A p.V336M | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as COSV61140052; called by muse, mutect2, varscan2
- ANO4 | c.1075G>A p.G359S (on ENST00000392977 / NM_001286615.2; = p.G324S on NM_178826.4) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.982); catalogued as rs755674505, COSV54595826, COSV54608143; called by muse, mutect2, varscan2
- ANPEP | c.2267C>T p.A756V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.562); catalogued as COSV100262963; called by muse, mutect2, varscan2
- AOAH | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV51748418; called by muse, mutect2, varscan2
- APAF1 | c.730G>C p.D244H (on ENST00000551964 / NM_181861.2; = p.D233H on NM_001160.3) | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59666879; called by muse, mutect2, varscan2
- APBB1IP | c.283C>T p.H95Y | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs138851282, COSV63303843; called by muse, mutect2, varscan2
- ARHGAP32 | c.1163T>C p.V388A (on ENST00000310343 / NM_001378025.1; = p.V39A on NM_014715.4) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV59853596; called by muse, mutect2, varscan2
- ARHGEF17 | c.4811C>T p.P1604L | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV55236191; called by muse, mutect2, varscan2
- ASCC3 | c.2510C>T p.S837F | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1057199043, COSV61232100; called by muse, mutect2, varscan2
- ASS1 | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV61690373; called by muse, mutect2, varscan2
- ATP2A3 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs759123767, COSV59228023; called by muse, mutect2
- ATP5MC2 | c.157C>T p.L53F | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs769609879, COSV100100984; called by muse, mutect2, varscan2
- ATR | c.6620C>T p.S2207F | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV63390218; called by muse, mutect2, varscan2
- AZGP1 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.014); catalogued as COSV52798975; called by muse, mutect2
- BACH2 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57603834; called by muse, mutect2, varscan2
- BAHCC1 | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.139); catalogued as rs1477872026, COSV100311531; called by muse, mutect2, varscan2
- BAHCC1 | c.1595C>T p.P532L | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as rs782044634, COSV100311534; called by muse, mutect2, varscan2
- BAZ2A | c.2757C>T p.S919= | Splice Region (SNP) | VAF 4/20 reads (20%) | catalogued as COSV51641569; called by muse, mutect2
- BEST3 | c.1997C>T p.S666L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV58304276; called by muse, mutect2, varscan2
- BGN | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 51/73 reads (70%) | SIFT tolerated (0.23); PolyPhen benign (0.078); catalogued as COSV59037926; called by muse, mutect2, varscan2
- BHMT2 | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.924); catalogued as COSV54874172; called by muse, mutect2, varscan2
- BICDL2 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV66370106; called by muse, mutect2, varscan2
- BNIP1 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV51571705; called by muse, mutect2, varscan2
- BNIP5 | c.892A>G p.K298E | Missense Mutation (SNP) | VAF 100/238 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV71325787; called by muse, mutect2, varscan2
- BRINP3 | c.1854G>A p.W618* | Nonsense Mutation (SNP) | VAF 148/344 reads (43%) | catalogued as COSV66513576, COSV66524701; called by muse, mutect2, varscan2
- BRMS1 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.177); catalogued as rs1432837451, COSV60928293; called by muse, mutect2
- BTAF1 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV56437907; called by muse, mutect2, varscan2
- BTN1A1 | c.946C>T p.L316F | Missense Mutation (SNP) | VAF 99/252 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1561885481, COSV99764258, COSV99764328; called by muse, mutect2, varscan2
- C19orf57 | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 33/104 reads (32%) | catalogued as COSV60967318; called by muse, mutect2, varscan2
- C1QL4 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.018); catalogued as rs939588157, COSV57745486; called by muse, mutect2, varscan2
- C1RL | c.601C>T p.Q201* | Nonsense Mutation (SNP) | VAF 18/41 reads (44%) | catalogued as rs267603661, COSV56926143; called by muse, mutect2, varscan2
- C20orf194 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs779631164, COSV52701012; called by muse, mutect2, varscan2
- C2CD2 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.089); catalogued as COSV66855279; called by muse, mutect2, varscan2
- C2orf16 | c.2927G>A p.R976K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as rs768214000, COSV62677559; called by muse, mutect2, varscan2
- CACNA1E | c.5296G>A p.E1766K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV62411806; called by muse, mutect2, varscan2
- CACNA2D1 | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | catalogued as rs1554412565, COSV62387100; called by muse, mutect2, varscan2
- CALML5 | c.321G>A p.M107I | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as COSV66702682; called by muse, varscan2
- CALR3 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.95); PolyPhen benign (0.06); catalogued as rs199535524; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAMSAP2 | c.2809C>T p.P937S (on ENST00000236925 / NM_001297707.2; = p.P926S on NM_203459.3) | Missense Mutation (SNP) | VAF 90/161 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV52675484; called by muse, mutect2, varscan2
- CAVIN2 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV58423984, COSV58425263; called by muse, mutect2, varscan2
- CCDC160 | c.764G>A p.G255E | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV66251891; called by muse, varscan2
- CCDC39 | c.1211A>G p.K404R | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.334); catalogued as COSV56490938; called by muse, mutect2, varscan2
- CCDC65 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs763737404, COSV57197404; called by muse, mutect2, varscan2
- CD36 | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs766072001, COSV59217553; called by muse, mutect2, varscan2
- CDH1 | c.2602C>T p.R868C | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs864622630, COSV55738596; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH9 | c.602T>A p.I201K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50388826; called by muse, mutect2, varscan2
- CDX2 | c.614T>A p.F205Y | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV66829820; called by muse, mutect2, varscan2
- CEMIP2 | c.2272C>T p.R758* | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as rs746389869, COSV65488164; called by muse, mutect2, varscan2
- CEP162 | c.3700C>T p.L1234F | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV57621494, COSV57622914; called by muse, mutect2, varscan2
- CETN1 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as rs1254036750, COSV100511317, COSV59121082; called by muse, mutect2
- CFAP20DC | c.2211G>A p.M737I (on ENST00000482387 / NM_001351530.2; = p.M486I on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV55925572; called by muse, mutect2, varscan2
- CFAP43 | c.3511T>G p.L1171V | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63854589; called by muse, mutect2, varscan2
- CFAP54 | c.7643T>G p.L2548R | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV61574319; called by muse, mutect2, varscan2
- CFAP91 | c.244C>T p.H82Y | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV99847058; called by muse, varscan2
- CFHR5 | c.948G>A p.W316* | Nonsense Mutation (SNP) | VAF 24/75 reads (32%) | catalogued as COSV56826408; called by muse, mutect2, varscan2
- CHRDL2 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV55224507; called by muse, mutect2, varscan2
- CILP2 | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.823); catalogued as rs376814408; called by muse, mutect2, varscan2
- CLASP1 | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV55335234; called by muse, mutect2, varscan2
- CLC | c.132G>A p.M44I | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.043); catalogued as COSV55686209; called by muse, mutect2, varscan2
- CLDN8 | c.532G>A p.G178R | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV54525622; called by muse, mutect2, varscan2
- CLEC6A | c.593G>A p.R198K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.066); catalogued as COSV65987964; called by muse, mutect2, varscan2
- CMKLR1 | c.1077G>A p.M359I (on ENST00000312143 / NM_001142344.2; = p.M357I on NM_004072.3) | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV56441093; called by muse, mutect2, varscan2
- CNN2 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.216); catalogued as rs138515103; called by muse, varscan2
- CNTN5 | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV54279105; called by muse, mutect2, varscan2
- CNTNAP2 | c.3109C>T p.P1037S | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs541853843, COSV62237254; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL14A1 | c.1865-1G>A p.X622_splice | Splice Site (SNP) | VAF 15/60 reads (25%) | catalogued as COSV52864502; called by muse, mutect2, varscan2
- COL19A1 | c.1619G>A p.G540E | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763134497, COSV59583254; called by muse, mutect2, varscan2
- COL21A1 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs267601087, COSV55152247; called by muse, mutect2, varscan2
- COL24A1 | c.1759C>T p.P587S | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs576997115, COSV65311512; called by muse, mutect2, varscan2
- COL5A1 | c.2918G>A p.G973E | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65673308; called by muse, mutect2, varscan2
- COL5A3 | c.2768G>A p.G923E | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53412934; called by muse, mutect2, varscan2
- CORO7 | c.1670C>T p.P557L | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as rs113335841, COSV52033043; called by muse, mutect2, varscan2
- CPA3 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as rs145828911, COSV56044334, COSV56047504; called by muse, mutect2, varscan2
- CPAMD8 | c.4166G>A p.R1389Q (on ENST00000651564; = p.R1342Q on NM_015692.5) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs184781786, COSV71596032; called by muse, mutect2, varscan2
- CPNE4 | c.75A>C p.K25N | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV101456657; called by muse, mutect2, varscan2
- CPT1C | c.1162G>A p.G388S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV54921499; called by muse, mutect2, varscan2
- CPXCR1 | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.18); PolyPhen benign (0.445); catalogued as COSV52160856; called by muse, mutect2, varscan2
- CRACDL | c.459G>A p.M153I | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.895); catalogued as COSV67408213; called by muse, mutect2, varscan2
- CRIP3 | c.209G>A p.G70D | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV99240293; called by muse, mutect2, varscan2
- CRIP3 | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as COSV51486338, COSV99240294; called by muse, mutect2, varscan2
- CSF2RB | c.2665G>A p.E889K | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV53260190; called by muse, mutect2, varscan2
- CSMD1 | c.7618G>A p.E2540K (on ENST00000520002; = p.E2539K on NM_033225.6) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as COSV59298741, COSV59365790; called by muse, mutect2, varscan2
- CSMD2 | c.213T>A p.F71L | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.983); catalogued as rs753186109, COSV53947324; called by muse, mutect2, varscan2
- CSN2 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs781240671, COSV61991811, COSV61992523; called by muse, mutect2, varscan2
- CSNK1G1 | c.527G>A p.G176D | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV57312914; called by muse, mutect2, varscan2
- CXorf21 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV66763157; called by muse, mutect2, varscan2
- CYP3A43 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.433); catalogued as COSV55936966; called by muse, mutect2, varscan2
- CYP46A1 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 69/261 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV55896133; called by muse, mutect2, varscan2
- CYP4Z1 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs868399298, COSV61964879; called by muse, mutect2, varscan2
- DCDC1 | c.3041C>T p.S1014F (on ENST00000597505 / NM_001367979.1; = p.S121F on NM_020869.3) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV60310775; called by muse, mutect2, varscan2
- DCHS1 | c.5399T>C p.L1800P | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100201949; called by muse, mutect2
- DCSTAMP | c.901C>T p.L301F | Missense Mutation (SNP) | VAF 59/251 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.047); catalogued as COSV52579410; called by muse, mutect2, varscan2
- DEFA6 | c.287G>A p.R96K | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.191); catalogued as COSV52406435; called by muse, mutect2, varscan2
- DEFB136 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV66364015; called by muse, mutect2, varscan2
- DGKE | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52348678; called by muse, mutect2, varscan2
- DHX36 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV57675937; called by muse, mutect2, varscan2
- DLC1 | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); catalogued as COSV52321053; called by muse, mutect2, varscan2
- DLGAP2 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70102618; called by muse, mutect2, varscan2
- DMPK | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767864367, COSV52177935; called by muse, varscan2
- DNAH5 | c.6739C>T p.Q2247* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as COSV54244732; called by muse, mutect2, varscan2
- DNAH5 | c.6149C>T p.S2050F | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs865859969, COSV54207857; called by muse, mutect2, varscan2
- DNAH8 | c.1501C>T p.Q501* | Nonsense Mutation (SNP) | VAF 9/77 reads (12%) | catalogued as rs1554208586, COSV59471446; called by muse, mutect2, varscan2
- DNAH8 | c.3053G>T p.R1018L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.269); catalogued as COSV59464146, COSV59471463; called by muse, mutect2, varscan2
- DNAH8 | c.8819C>T p.S2940L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs1394133909, COSV59440794; called by muse, mutect2, varscan2
- DOK6 | c.723G>A p.M241I | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV66935866; called by muse, mutect2, varscan2
- DPRX | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 27/93 reads (29%) | catalogued as rs150237904; called by muse, mutect2, varscan2
- DSC1 | c.1328C>T p.S443F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.678); catalogued as COSV57149838; called by muse, mutect2, varscan2
- DSC3 | c.1816G>A p.A606T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs1474461683, COSV64574703; called by mutect2, varscan2
- DSEL | c.1203G>T p.W401C | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59493754; called by muse, mutect2, varscan2
- DSG4 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs1042293964, COSV57391132; called by muse, mutect2
- DYNC2H1 | c.3576C>T p.I1192= | Splice Region (SNP) | VAF 7/18 reads (39%) | catalogued as rs180790392; called by muse, mutect2, varscan2
- DYNLRB2 | c.205C>T p.L69F | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.651); catalogued as COSV58416729; called by muse, mutect2, varscan2
- EFCAB5 | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 39/196 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV57934929; called by muse, mutect2, varscan2
- EGF | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as COSV54482949; called by muse, mutect2, varscan2
- EGFLAM | c.1868C>T p.P623L | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.354); catalogued as rs370628892, COSV100380521; called by muse, mutect2, varscan2
- EIF4G1 | c.3593C>T p.P1198L (on ENST00000346169 / NM_198241.3; = p.P1003L on NM_004953.5) | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as COSV59993040; called by muse, mutect2, varscan2
- EML3 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV53884139; called by muse, mutect2, varscan2
- EPHA3 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs753700696, COSV60696515, COSV60700528; called by muse, mutect2, varscan2
- EPHA3 | c.2416G>A p.D806N | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60702835; called by muse, mutect2, varscan2
- EPHX2 | c.515C>T p.T172I | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1234786380, COSV66845796; called by muse, mutect2
- ERC2 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.242); catalogued as COSV55652379; called by muse, mutect2, varscan2
- EVPL | c.3865G>A p.E1289K | Missense Mutation (SNP) | VAF 91/206 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV56914572; called by muse, mutect2, varscan2
- F2RL1 | c.961C>T p.H321Y | Missense Mutation (SNP) | VAF 113/372 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV56996541; called by muse, mutect2, varscan2
- FAM135B | c.1970C>T p.S657F | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV52716564; called by muse, mutect2, varscan2
- FANCE | c.485G>A p.R162K | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV57690803; called by muse, mutect2, varscan2
- FASTKD5 | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.203); catalogued as COSV53908499; called by muse, mutect2, varscan2
- FAT3 | c.2372G>A p.R791Q | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs199786266; called by muse, mutect2, varscan2
- FAT4 | c.8720G>A p.G2907E | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58702213; called by muse, mutect2, varscan2
- FBP1 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV100941145; called by muse, mutect2, varscan2
- FBXL13 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0.013); catalogued as rs750994268, COSV57542560; called by muse, mutect2
- FBXW12 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV56485049; called by muse, mutect2, varscan2
- FER1L6 | c.2215G>A p.D739N | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.811); catalogued as COSV67549924, COSV67552083; called by muse, mutect2, varscan2
- FEZF2 | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.143); catalogued as COSV51864180; called by muse, mutect2, varscan2
- FGA | c.2473G>A p.G825S | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV57399407; called by muse, mutect2, varscan2
- FGF12 | c.575C>T p.T192I (on ENST00000454309 / NM_021032.5; = p.T130I on NM_004113.6) | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV53182761; called by muse, mutect2, varscan2
- FLG | c.9908G>A p.G3303E | Missense Mutation (SNP) | VAF 366/820 reads (45%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); catalogued as COSV64246240; called by muse, varscan2
- FMN2 | c.2606C>T p.S869F | Missense Mutation (SNP) | VAF 61/123 reads (50%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1362498929, COSV60446434; called by muse, mutect2, varscan2
- FMO4 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63001757; called by muse, mutect2, varscan2
- GABPB1 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.979); catalogued as COSV55017007; called by muse, mutect2, varscan2
- GABRA2 | c.1091A>C p.N364T | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.038); catalogued as COSV100734162; called by muse, mutect2, varscan2
- GABRA3 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV64798831, COSV64804398; called by muse, mutect2, varscan2
- GABRA5 | c.1307T>G p.L436W | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV59484187; called by muse, mutect2, varscan2
- GABRB3 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV54678375; called by muse, mutect2, varscan2
- GABRG2 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62721292; called by muse, mutect2, varscan2
- GAL3ST1 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs1256848658, COSV100143050; called by muse, mutect2, varscan2
- GALNT13 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as COSV67233547; called by muse, mutect2, varscan2
- GALNT13 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.052); catalogued as rs868521163, COSV67211168; called by muse, mutect2, varscan2
- GALNT14 | c.1036G>A p.G346R | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61109578; called by muse, mutect2, varscan2
- GALNT16 | c.1366G>A p.G456R | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.962); catalogued as COSV61887330; called by muse, mutect2, varscan2
- GALP | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as COSV62000864; called by muse, mutect2, varscan2
- GDA | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV52992291; called by muse, mutect2, varscan2
- GHSR | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53840859; called by muse, mutect2, varscan2
- GIGYF1 | c.2021C>T p.P674L | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1435478752, COSV51945607; called by muse, mutect2, varscan2
- GIN1 | c.1447C>T p.R483C | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs782158464, COSV67535957; called by muse, mutect2, varscan2
- GIP | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.831); catalogued as rs963387974, COSV62467618; called by muse, mutect2, varscan2
- GJA1 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867908644, COSV56997798; called by muse, mutect2, varscan2
- GJA5 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 68/142 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.046); catalogued as COSV54786058; called by muse, mutect2, varscan2
- GLYAT | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV53538375; called by muse, varscan2
- GNL3 | c.210+1G>T p.X70_splice | Splice Site (SNP) | VAF 37/118 reads (31%) | catalogued as COSV66920997; called by muse, mutect2, varscan2
- GPR12 | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as COSV67344750; called by muse, mutect2, varscan2
- GPR149 | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV67669201; called by muse, mutect2
- GPR20 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV66684855; called by muse, mutect2
- GPRIN1 | c.2876C>T p.P959L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.303); catalogued as COSV56143453; called by muse, mutect2, varscan2
- GPRIN3 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs763784358, COSV60886143; called by muse, mutect2, varscan2
- GRAMD1B | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.37); PolyPhen probably damaging (0.996); catalogued as rs752907684, COSV59209204; called by muse, mutect2, varscan2
- GRIA1 | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.281); catalogued as rs1335115184, COSV53594707; called by muse, mutect2, varscan2
- GRIN3A | c.1927G>A p.D643N | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1288217148, COSV62452012, COSV62457064; called by muse, mutect2, varscan2
- GUK1 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as rs368505522; called by muse, mutect2
- GXYLT1 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 19/63 reads (30%) | catalogued as COSV55136974; called by muse, mutect2, varscan2
- HAPLN1 | c.523C>T p.H175Y | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as rs1466610710, COSV57150978; called by muse, mutect2, varscan2
- HAS2 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58263652; called by muse, mutect2, varscan2
- HBG2 | c.269G>A p.S90N | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.658); catalogued as COSV100400600, COSV57964310; called by muse, mutect2, varscan2
- HDC | c.1321C>T p.Q441* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as COSV51077617; called by muse, mutect2, varscan2
- HEPH | c.2636C>T p.S879F (on ENST00000343002; = p.S612F on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV57962906, COSV57966144; called by muse, mutect2, varscan2
- HMCN1 | c.13534C>T p.R4512* | Nonsense Mutation (SNP) | VAF 64/158 reads (41%) | catalogued as rs766364489, COSV54929103; called by muse, mutect2, varscan2
- HNF4A | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.444); catalogued as rs748452860, COSV57382487; called by muse, mutect2, varscan2
- IGKV1D-17 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as rs1158527266; called by muse, mutect2, varscan2
- IGSF10 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV99179087; called by muse, mutect2, varscan2
- IGSF10 | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as COSV56782623, COSV99179098; called by muse, mutect2, varscan2
- IL1RL2 | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.927); catalogued as rs868856349, COSV51817819; called by muse, mutect2, varscan2
- IL9R | c.576G>A p.W192* | Nonsense Mutation (SNP) | VAF 21/34 reads (62%) | catalogued as COSV54901517; called by muse, mutect2, varscan2
- ILDR2 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV54834429; called by muse, mutect2, varscan2
- IMMP2L | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59261471; called by muse, mutect2, varscan2
- INTS3 | c.927G>T p.M309I | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.888); catalogued as COSV59680676; called by muse, mutect2, varscan2
- IRAG1 | c.2162C>T p.S721F | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs968229354, COSV70212577; called by muse, mutect2, varscan2
- IRAG1 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV70212584; called by muse, mutect2, varscan2
- ITGAD | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 63/217 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as rs143276012; called by muse, mutect2, varscan2
- ITGB3 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV101457574; called by muse, mutect2, varscan2
- ITIH3 | c.2569G>A p.D857N | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as rs1390004408, COSV56577381; called by muse, mutect2, varscan2
- ITK | c.970C>T p.Q324* | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | catalogued as COSV68435290, COSV68435448; called by muse, mutect2, varscan2
- ITLN1 | c.833A>T p.Q278L | Missense Mutation (SNP) | VAF 64/128 reads (50%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV58276354; called by mutect2, varscan2
- IZUMO1R | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60623276; called by muse, mutect2, varscan2
- JAK3 | c.1801G>A p.E601K | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV71687088; called by muse, mutect2, varscan2
- KALRN | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); catalogued as COSV53775926; called by muse, mutect2, varscan2
- KAT6A | c.4397C>T p.P1466L | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55910698; called by muse, mutect2, varscan2
- KBTBD3 | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as rs758136853, COSV73241572; called by muse, mutect2, varscan2
- KCNC2 | c.143C>T p.T48I | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.163); catalogued as COSV54376301; called by muse, mutect2, varscan2
- KCNH4 | c.1586A>G p.N529S | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV52920295; called by muse, mutect2, varscan2
- KCNJ2 | c.45A>T p.E15D | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.083); catalogued as COSV54663233; called by muse, mutect2, varscan2
- KCNJ6 | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV55720279; called by muse, mutect2, varscan2
- KCNK10 | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as COSV56639635; called by muse, mutect2, varscan2
- KCNN1 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV55839145; called by muse, mutect2
- KCNT2 | c.2636G>A p.R879Q | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV54101026; called by muse, mutect2, varscan2
- KDR | c.2077A>T p.N693Y | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV55773104; called by muse, mutect2, varscan2
- KERA | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57130792; called by muse, mutect2, varscan2
- KIAA1217 | c.1361A>T p.K454I | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56821477; called by muse, mutect2, varscan2
- KIF3B | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV65228936; called by muse, mutect2, varscan2
- KIR3DL2 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.926); catalogued as COSV54392058; called by muse, mutect2, varscan2
- KLHDC8A | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65679173; called by muse, mutect2, varscan2
- LAMA5 | c.858G>A p.R286= | Splice Region (SNP) | VAF 4/10 reads (40%) | catalogued as rs544062369, COSV99439523; called by muse, varscan2
- LAMA5 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs962267864, COSV99439530; called by muse, mutect2, varscan2
- LGSN | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV65726718; called by muse, mutect2, varscan2
- LILRB4 | c.866G>A p.R289K | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV54407819; called by muse, mutect2, varscan2
- LIPH | c.1239G>A p.M413I | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV56183018; called by muse, mutect2, varscan2
- LONRF1 | c.784A>G p.K262E | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.014); catalogued as COSV68037581; called by muse, mutect2, varscan2
- LRP1B | c.1495C>T p.R499W | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs562471696, COSV67259811; called by muse, mutect2, varscan2
- LRRC15 | c.1045C>T p.H349Y | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61651083, COSV61651178; called by muse, mutect2, varscan2
- LRRC3B | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs868070081, COSV67522078; called by muse, mutect2, varscan2
- LRRK2 | c.3463G>A p.V1155M | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs1436779603, COSV54151388; called by muse, mutect2, varscan2
- LUC7L2 | c.625C>T p.H209Y | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54929273; called by muse, mutect2, varscan2
- LUZP2 | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as COSV61196424, COSV61214653; called by muse, mutect2, varscan2
- MACC1 | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768468841, COSV100256143, COSV60545446; called by muse, mutect2, varscan2
- MAEL | c.772C>T p.L258F | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.379); catalogued as COSV63112348, COSV63112391; called by muse, mutect2, varscan2
- MAGEC1 | c.2507C>T p.S836F | Missense Mutation (SNP) | VAF 61/104 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV53578996; called by muse, mutect2, varscan2
- MAGEL2 | c.3694G>A p.E1232K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); catalogued as rs751825273, COSV58568073; called by muse, mutect2, varscan2
- MAN1A1 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as COSV63784048, COSV63784750; called by muse, mutect2, varscan2
- MAP3K21 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs766605671, COSV64042349; called by muse, mutect2, varscan2
- MAP4 | c.2689C>T p.R897W | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs374556358; called by muse, mutect2, varscan2
- MAPK4 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs777838970, COSV68543364; called by muse, mutect2, varscan2
- MEF2C | c.1289C>T p.S430L | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV60926568; called by muse, mutect2, varscan2
- MEP1A | c.2147G>A p.G716D | Missense Mutation (SNP) | VAF 89/210 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.322); catalogued as rs761133593, COSV57917983; called by muse, mutect2, varscan2
- MEPE | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.156); catalogued as rs551712026, COSV63071744, COSV63073982; called by muse, mutect2, varscan2
- MGA | c.5605C>T p.Q1869* (on ENST00000219905 / NM_001164273.1; = p.Q1660* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 27/52 reads (52%) | catalogued as COSV54960661, COSV99578882; called by muse, mutect2, varscan2
- MGAM | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs373200528; called by muse, mutect2, varscan2
- MGAT5B | c.1978C>T p.P660S (on ENST00000569840 / NM_001199172.2; = p.P658S on NM_144677.3) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as COSV56934634; called by muse, mutect2, varscan2
- MINDY4 | c.1903C>T p.L635F | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54677393; called by muse, mutect2, varscan2
- MLIP | c.326G>A p.R109K | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.92); PolyPhen benign (0.006); catalogued as COSV51434890; called by muse, mutect2, varscan2
- MLIP | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as COSV51428217; called by muse, mutect2, varscan2
- MROH2B | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.99); catalogued as COSV68181007; called by muse, mutect2, varscan2
- MROH7 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 38/57 reads (67%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); catalogued as COSV59876159; called by muse, mutect2, varscan2
- MRTFA | c.2206C>T p.P736S | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.049); catalogued as rs758482858, COSV62935641; called by muse, mutect2, varscan2
- MS4A14 | c.1412G>A p.W471* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as COSV55737153; called by muse, mutect2, varscan2
- MSMO1 | c.808C>T p.R270* | Nonsense Mutation (SNP) | VAF 14/51 reads (27%) | catalogued as COSV54970067; called by muse, mutect2, varscan2
- MSR1 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs1371483368, COSV50525348; called by muse, mutect2, varscan2
- MUC16 | c.2981C>T p.A994V | Missense Mutation (SNP) | VAF 58/224 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.336); catalogued as COSV67456142; called by muse, mutect2, varscan2
- MUC17 | c.10975C>T p.P3659S | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.599); catalogued as rs759475798, COSV60299252; called by muse, mutect2, varscan2
- MYBPC1 | c.1345G>A p.E449K (on ENST00000550270 / NM_206820.2; = p.E474K on NM_002465.4) | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV62252081, COSV62256429; called by muse, mutect2, varscan2
- MYH13 | c.4391T>C p.L1464P | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.317); catalogued as rs753814640, COSV52838671; called by muse, mutect2, varscan2
- MYH14 | c.1067G>A p.G356E | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV51827967; called by muse, mutect2, varscan2
- MYH14 | c.3070C>T p.R1024C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs747770727, COSV51809763; called by muse, mutect2, varscan2
- MYH15 | c.2198+1G>A p.X733_splice | Splice Site (SNP) | VAF 24/99 reads (24%) | catalogued as COSV56317012; called by muse, mutect2, varscan2
- MYH2 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as rs767416022, COSV55445528; called by muse, mutect2, varscan2
- MYH3 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV56868693; called by muse, mutect2, varscan2
- MYO1F | c.1301C>T p.T434I | Missense Mutation (SNP) | VAF 86/264 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as COSV57798912; called by muse, mutect2, varscan2
- MYO3A | c.890T>C p.L297P | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56343638; called by muse, mutect2, varscan2
- MYO5C | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764941433, COSV55910680; called by muse, mutect2, varscan2
- NADK2 | c.664A>T p.I222F (on ENST00000381937 / NM_001085411.3; = p.I59F on NM_153013.4) | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV56938867; called by muse, mutect2, varscan2
- NCAN | c.1436G>A p.R479K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV53056327, COSV99387088; called by muse, mutect2, varscan2
- NCKAP1L | c.3325C>T p.P1109S | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53210783; called by muse, mutect2, varscan2
- NCOR1 | c.2833C>T p.P945S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.091); catalogued as COSV51975770; called by muse, mutect2, varscan2
- NCR1 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as rs1045866790, COSV52557900; called by muse, mutect2, varscan2
- NDST4 | c.1687C>A p.L563I | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.027); catalogued as COSV52132086; called by muse, mutect2, varscan2
- NDST4 | c.324G>A p.M108I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV52132098; called by muse, mutect2, varscan2
- NEB | c.1849G>A p.D617N | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.997); catalogued as COSV50808237; called by muse, mutect2, varscan2
- NEBL | c.2911G>A p.D971N | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65805087; called by muse, mutect2, varscan2
- NETO1 | c.298C>T p.H100Y | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.2); catalogued as COSV55012971; called by muse, mutect2, varscan2
- NEUROD1 | c.65G>A p.W22* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | catalogued as rs1332890945, COSV54550634; called by muse, mutect2, varscan2
- NIPBL | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.607); catalogued as COSV56961592; called by muse, mutect2, varscan2
- NLRP11 | c.1895T>G p.M632R | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.014); catalogued as COSV64088081, COSV64088460; called by muse, mutect2, varscan2
- NMNAT3 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs774032862, COSV56158540; called by muse, mutect2, varscan2
- NMT1 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51961945; called by muse, mutect2, varscan2
- NOMO1 | c.3256C>T p.P1086S | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV99814452; called by muse, mutect2, varscan2
- NOMO1 | c.3257C>T p.P1086L | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs995376623, COSV99814455; called by muse, mutect2, varscan2
- NOTCH4 | c.3587G>A p.G1196E | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.841); catalogued as COSV66678640; called by muse, mutect2, varscan2
- NPVF | c.161A>G p.E54G | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs780370589, COSV56061370; called by muse, mutect2, varscan2
- NPY1R | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as rs1313572042, COSV56715805, COSV99648830; called by muse, mutect2, varscan2
- NRXN1 | c.4391C>T p.S1464F | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV60513495, COSV60515579; called by muse, mutect2, varscan2
- NUF2 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV54845736, COSV54848263; called by muse, mutect2, varscan2
- NUP155 | c.3751C>T p.L1251F (on ENST00000231498 / NM_153485.3; = p.L1192F on NM_004298.4) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764584056, COSV51533384; called by muse, mutect2, varscan2
- ODF2L | c.106C>T p.L36F | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.684); catalogued as COSV54017373; called by muse, mutect2, varscan2
- OPN4 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54118577; called by muse, mutect2, varscan2
- OR11G2 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs374887720; called by muse, mutect2, varscan2
- OR14K1 | c.584G>A p.S195N | Missense Mutation (SNP) | VAF 82/172 reads (48%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99315126; called by muse, mutect2, varscan2
- OR1N2 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 63/202 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV65460257; called by muse, mutect2
- OR2A25 | c.163C>T p.H55Y | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV68717549; called by muse, mutect2, varscan2
- OR2H1 | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 51/253 reads (20%) | catalogued as rs890494437, COSV65811203; called by muse, mutect2, varscan2
- OR2T12 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as COSV58775820; called by muse, mutect2, varscan2
- OR2T2 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV61618765; called by muse, mutect2, varscan2
- OR2W1 | c.732T>A p.H244Q | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs758363849, COSV65851825; called by muse, mutect2, varscan2
- OR4D9 | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV61435154; called by muse, varscan2
- OR4E2 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV57731870, COSV57732167; called by muse, mutect2, varscan2
- OR51A7 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs147819477, COSV63788824; called by muse, mutect2, varscan2
- OR51D1 | c.697C>T p.L233F | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.722); catalogued as rs1277834226, COSV62914475, COSV62914692; called by muse, mutect2, varscan2
- OR51E1 | c.249A>T p.K83N | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV67810729; called by muse, mutect2, varscan2
- OR51F1 | c.471G>A p.M157I | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58580510; called by muse, mutect2, varscan2
- OR51G2 | c.859C>T p.L287F | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1203461371, COSV58994349; called by muse, mutect2, varscan2
- OR51V1 | c.148C>T p.H50Y | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.042); catalogued as COSV58316057; called by muse, mutect2, varscan2
- OR5AP2 | c.221T>A p.F74Y | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV57258400; called by muse, mutect2, varscan2
- OR5B12 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV56903931; called by muse, mutect2, varscan2
- OR5H14 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1559807805, COSV71193922; called by muse, mutect2, varscan2
- OR5H15 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as COSV62948504, COSV62948786; called by muse, mutect2, varscan2
- OR5J2 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV56622684; called by muse, mutect2, varscan2
- OR5M11 | c.413G>A p.R138K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV73141973; called by muse, mutect2, varscan2
- OR6C1 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV65573199; called by muse, mutect2, varscan2
- OR6C3 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.246); catalogued as COSV65571532; called by muse, varscan2
- OR6C3 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.247); catalogued as COSV65571480, COSV65571698; called by muse, varscan2
- OR6X1 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60010280; called by muse, mutect2, varscan2
- OR8G5 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.013); catalogued as rs992029489, COSV100422388; called by muse, mutect2, varscan2
- OSBPL3 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.652); catalogued as COSV57660949; called by muse, mutect2, varscan2
- PARD3B | c.2380G>A p.E794K (on ENST00000406610 / NM_001302769.2; = p.E732K on NM_152526.6) | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV62508732; called by muse, mutect2, varscan2
- PARP11 | c.342C>T p.F114= | Splice Region (SNP) | VAF 31/108 reads (29%) | catalogued as COSV57396862; called by muse, mutect2, varscan2
- PARP15 | c.892G>A p.E298K (on ENST00000464300 / NM_001113523.3; = p.E64K on NM_152615.2) | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.672); catalogued as COSV59971600; called by muse, mutect2, varscan2
- PARP15 | c.1488G>A p.M496I (on ENST00000464300 / NM_001113523.3; = p.M262I on NM_152615.2) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV59974303; called by muse, mutect2, varscan2
- PARP15 | c.1927C>T p.P643S (on ENST00000464300 / NM_001113523.3; = p.P409S on NM_152615.2) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as COSV59973482; called by muse, mutect2, varscan2
- PBX1 | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV63347130; called by muse, mutect2, varscan2
- PCDHA6 | c.2270G>A p.R757K | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.005); catalogued as rs147693617, COSV65346547; called by muse, mutect2, varscan2
- PCDHA7 | c.2018G>A p.G673D | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.461); catalogued as COSV65339493; called by muse, mutect2, varscan2
- PCDHB16 | c.2257G>A p.V753M | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.045); catalogued as COSV53368691; called by muse, mutect2, varscan2
- PCDHB2 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52031260; called by muse, mutect2, varscan2
- PCDHGA2 | c.2060C>T p.S687L | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); catalogued as COSV53952182; called by muse, mutect2, varscan2
- PCLO | c.11342G>A p.R3781Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs866846868, COSV61657462; called by muse, mutect2, varscan2
- PCNX2 | c.1676C>T p.S559F | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50854694; called by muse, mutect2, varscan2
- PCNX2 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 83/176 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1471016554, COSV50854845; called by muse, mutect2, varscan2
- PCSK5 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65094181; called by muse, mutect2, varscan2
- PDE1B | c.1444C>T p.R482C | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs764032346, COSV54495233; called by muse, mutect2, varscan2
- PDE1C | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs143359144; called by muse, mutect2, varscan2
- PDLIM1 | c.206G>A p.R69K | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61473575, COSV61474716; called by muse, mutect2, varscan2
- PEG3 | c.3566A>C p.Q1189P | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV55643545; called by muse, mutect2
- PEG3 | c.1801G>A p.E601K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.332); catalogued as COSV55643556; called by muse, mutect2, varscan2
- PHLPP2 | c.2051C>T p.P684L | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62426712; called by muse, mutect2, varscan2
- PI4KB | c.909+2T>C p.X303_splice (on ENST00000368873 / NM_001369623.1; = p.X315_splice on NM_002651.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 53/112 reads (47%) | catalogued as COSV55020409; called by muse, mutect2, varscan2
- PKD2L1 | c.2362G>A p.A788T | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV58395569; called by muse, mutect2, varscan2
- PKHD1L1 | c.11917A>T p.I3973F | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV65749991; called by muse, mutect2, varscan2
- PLA2R1 | c.2131C>T p.H711Y | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs762051052, COSV51784775; called by muse, mutect2, varscan2
- PLCB4 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.982); catalogued as rs267606066, COSV53795991; called by muse, mutect2, varscan2
- PLCB4 | c.2404C>T p.R802* | Nonsense Mutation (SNP) | VAF 14/31 reads (45%) | catalogued as rs745489184, COSV53797545; called by muse, mutect2, varscan2
- PLCB4 | c.2960G>A p.G987E | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.461); catalogued as rs267606068, COSV53813440; called by muse, mutect2, varscan2
- PLCB4 | c.3081G>A p.M1027I | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV53799783, COSV53813462; called by muse, mutect2, varscan2
- PLCL2 | c.2657G>A p.G886E (on ENST00000615277 / NM_001144382.2; = p.G760E on NM_015184.5) | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV67624380; called by muse, mutect2, varscan2
- PMS2 | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV56223348; called by muse, mutect2, varscan2
- PON1 | c.144C>T p.I48= | Splice Region (SNP) | VAF 10/43 reads (23%) | catalogued as rs373190914; called by muse, mutect2, varscan2
- PPARGC1A | c.2173A>T p.T725S | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.89); PolyPhen probably damaging (0.983); catalogued as COSV53532192; called by muse, mutect2, varscan2
- PRDM5 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 63/243 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs142855444; called by muse, mutect2, varscan2
- PRDM9 | c.2576C>T p.P859L | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV57008553, COSV57011158; called by muse, mutect2, varscan2
- PREX2 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55761348, COSV55793576; called by muse, varscan2
- PREX2 | c.784G>T p.E262* | Nonsense Mutation (SNP) | VAF 12/52 reads (23%) | catalogued as COSV55793590; called by muse, varscan2
- PRRG3 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs369580690, COSV64850789, COSV64851019; called by muse, varscan2
- PRRX1 | c.571C>T p.L191F | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV53417503; called by muse, mutect2, varscan2
- PRSS48 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as COSV71613932, COSV71614119; called by muse, mutect2, varscan2
- PSG5 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 67/177 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61655035; called by muse, mutect2, varscan2
- PTGIS | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54836543; called by muse, mutect2, varscan2
- PTPN22 | c.828+1G>A p.X276_splice | Splice Site (SNP) | VAF 5/21 reads (24%) | catalogued as COSV63086149; called by muse, mutect2, varscan2
- PTPRO | c.2524A>C p.I842L | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769048447, COSV55519426; called by muse, mutect2, varscan2
- PTPRT | c.3988C>T p.R1330C | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1318044562, COSV61965535; called by muse, mutect2, varscan2
- PXDNL | c.3500A>G p.N1167S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV62495738; called by muse, mutect2
- PXDNL | c.873G>A p.M291I | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as rs1368521191, COSV62483047; called by muse, mutect2, varscan2
- PXYLP1 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs751037027, COSV53892414; called by muse, mutect2, varscan2
- PYHIN1 | c.1052G>A p.G351E | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63723600; called by muse, mutect2, varscan2
- RBM39 | c.1562C>T p.A521V (on ENST00000253363 / NM_001323424.2; = p.A515V on NM_004902.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV53617173; called by muse, mutect2
- RELN | c.5477G>A p.G1826E | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100632131, COSV59026309; called by muse, mutect2, varscan2
- RELN | c.961G>A p.G321R | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); catalogued as COSV59026325; called by muse, mutect2, varscan2
- REV3L | c.2782G>T p.E928* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as COSV62622102; called by muse, mutect2, varscan2
- RGS11 | c.1019G>A p.R340Q (on ENST00000397770 / NM_183337.3; = p.R319Q on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs149964951; called by muse, mutect2, varscan2
- RGS21 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.386); catalogued as COSV101313999, COSV69883489; called by muse, mutect2
- RGS4 | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 87/193 reads (45%) | SIFT tolerated (0.9); PolyPhen benign (0.314); catalogued as COSV100905548, COSV63357538; called by muse, mutect2, varscan2
- RHBDF2 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV57422162; called by muse, mutect2, varscan2
- ROBO2 | c.3785G>A p.R1262K | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.745); catalogued as COSV59931928; called by muse, mutect2, varscan2
- ROBO3 | c.2921C>T p.S974L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs767125636, COSV67302132; called by muse, mutect2, varscan2
- ROS1 | c.6393A>T p.E2131D | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63859959; called by muse, mutect2, varscan2
- RP1 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV55123810; called by muse, mutect2, varscan2
- RP1 | c.3698C>T p.S1233F | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs867536648, COSV55110747; called by muse, mutect2, varscan2
- RTL3 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV58185378; called by muse, mutect2, varscan2
- RUSC2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63429859; called by muse, mutect2, varscan2
- SAMD9L | c.2813C>T p.S938L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59084236; called by muse, mutect2, varscan2
- SBNO1 | c.3155C>T p.S1052F (on ENST00000420886; = p.S1051F on NM_018183.5) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV57344641; called by muse, mutect2
- SCN2A | c.5990G>A p.G1997E | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.476); catalogued as COSV51851908; called by muse, mutect2
- SCNN1G | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV55601126; called by muse, mutect2, varscan2
- SELPLG | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as COSV57314297; called by muse, mutect2, varscan2
- SENP1 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.221); catalogued as COSV50302511; called by muse, mutect2, varscan2
- SERPINA4 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54071201; called by muse, mutect2, varscan2
- SERPINB4 | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61985829; called by muse, mutect2, varscan2
- SEZ6L | c.2480G>A p.G827E | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50677552; called by muse, mutect2, varscan2
- SHANK1 | c.2278C>T p.P760S | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV53258906; called by muse, mutect2, varscan2
- SHB | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.062); catalogued as rs1423311650, COSV66629414; called by muse, mutect2, varscan2
- SHC3 | c.545G>A p.R182K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1201299517, COSV101011860, COSV65440171; called by muse, mutect2, varscan2
- SHKBP1 | c.1861C>T p.P621S | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.074); catalogued as COSV99190564; called by muse, mutect2, varscan2
- SIGLEC8 | c.1463G>A p.R488K | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.012); catalogued as rs750628232, COSV58475284; called by muse, mutect2, varscan2
- SIGLEC8 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as COSV58474239; called by muse, mutect2, varscan2
- SIM1 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.089); catalogued as COSV53495307; called by muse, mutect2, varscan2
- SIM1 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.99); PolyPhen benign (0.013); catalogued as rs767869221; called by muse, mutect2
- SLC12A5 | c.994G>A p.G332R (on ENST00000454036 / NM_001134771.2; = p.G309R on NM_020708.5) | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.035); catalogued as COSV54788436; called by muse, mutect2, varscan2
- SLC14A2 | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54913240; called by muse, mutect2, varscan2
- SLC17A2 | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781604221, COSV55354319; called by muse, mutect2, varscan2
- SLC22A10 | c.1363C>T p.H455Y | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.191); catalogued as rs745823442, COSV60423047; called by muse, mutect2, varscan2
- SLC22A9 | c.1111C>T p.H371Y | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV54169391; called by muse, mutect2, varscan2
- SLC24A3 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV60128497; called by muse, mutect2, varscan2
- SLC35G5 | c.646C>G p.P216A | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.389); catalogued as rs1442810597, COSV55314623; called by muse, mutect2, varscan2
- SLC45A4 | c.836G>A p.G279D (on ENST00000517878 / NM_001286646.2; = p.G228D on NM_001080431.2) | Missense Mutation (SNP) | VAF 52/223 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV50161795, COSV99202270; called by muse, mutect2, varscan2
- SLC9A4 | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766908354, COSV54828977; called by muse, mutect2, varscan2
- SLC9C1 | c.3220C>T p.P1074S | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.647); catalogued as COSV59891681; called by muse, mutect2, varscan2
- SLIT3 | c.1193C>A p.T398K | Missense Mutation (SNP) | VAF 78/238 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV60627659; called by muse, mutect2, varscan2
- SNAP91 | c.2458C>T p.P820S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV52130754; called by muse, mutect2, varscan2
- SNCAIP | c.2255C>T p.S752L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV54418586; called by muse, mutect2, varscan2
- SNED1 | c.3629G>A p.G1210E | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs1355918461, COSV60030686; called by muse, mutect2
- SORL1 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52760222; called by muse, mutect2, varscan2
- SOS2 | c.3544C>T p.P1182S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.521); catalogued as rs775431214, COSV53572369, COSV99366757; called by muse, mutect2, varscan2
- SOS2 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1364027643, COSV53567356; called by muse, mutect2
- SPHKAP | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.368); catalogued as COSV60875071; called by muse, mutect2, varscan2
- SPRED2 | c.178C>T p.H60Y | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.649); catalogued as COSV62695130; called by muse, mutect2, varscan2
- SPRYD3 | c.262A>C p.S88R | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV56855383; called by muse, mutect2, varscan2
- SPTA1 | c.5674G>A p.E1892K | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as rs1447521175, COSV63751177; called by muse, mutect2, varscan2
- SPTB | c.4753G>A p.E1585K | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.94); PolyPhen benign (0.028); catalogued as rs776051162, COSV67634284; called by muse, mutect2, varscan2
- SPTBN1 | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 21/69 reads (30%) | catalogued as COSV63343415; called by muse, mutect2, varscan2
- SRC | c.1478C>T p.S493F | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780921646, COSV62440846; called by muse, mutect2
- SRSF11 | c.561G>T p.L187F | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV63937590; called by muse, mutect2, varscan2
- SSR1 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV55204032; called by muse, mutect2, varscan2
- ST6GALNAC4 | c.309G>A p.M103I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | PolyPhen probably damaging (0.997); catalogued as rs867672395, COSV59130444; called by muse, mutect2
- STAP2 | c.271C>T p.L91F | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV74075489; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3121C>T p.R1041W | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as rs756405130, COSV59131674; called by muse, mutect2, varscan2
- STXBP4 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100894672; called by muse, mutect2, varscan2
- STXBP4 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as COSV100894674; called by muse, mutect2, varscan2
- STXBP5L | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV56528362; called by muse, mutect2, varscan2
- SULT1A1 | c.713C>T p.T238I | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as COSV59090097; called by muse, mutect2, varscan2
- SULT1E1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV56948340; called by muse, mutect2, varscan2
- SUN3 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.028); catalogued as COSV52049161; called by muse, mutect2, varscan2
- SUSD4 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as COSV59550805; called by muse, mutect2, varscan2
- SYBU | c.1726G>A p.E576K (on ENST00000276646 / NM_001099754.2; = p.E575K on NM_017786.6) | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52614138, COSV52621940, COSV99405889; called by muse, mutect2, varscan2
- SYNE1 | c.8257G>A p.D2753N (on ENST00000367255 / NM_182961.4; = p.D2760N on NM_033071.3) | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as COSV55066515; called by muse, mutect2, varscan2
- SYNPO | c.1244C>T p.S415F (on ENST00000394243 / NM_001166208.2; = p.S171F on NM_007286.6) | Missense Mutation (SNP) | VAF 71/231 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.495); catalogued as COSV56942182; called by muse, mutect2, varscan2
- SYT4 | c.104G>A p.W35* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV54903201; called by muse, mutect2, varscan2
- TACC2 | c.4463C>T p.A1488V | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs138712565; called by muse, mutect2, varscan2
- TACC2 | c.5460-1G>A p.X1820_splice | Splice Site (SNP) | VAF 4/12 reads (33%) | catalogued as COSV57767925; called by muse, mutect2
- TAGLN3 | c.357G>A p.G119= | Splice Region (SNP) | VAF 17/44 reads (39%) | catalogued as COSV56328947; called by muse, mutect2
- TARS3 | c.2092C>T p.R698C | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs774454880, COSV60109069; called by muse, mutect2, varscan2
- TBC1D25 | c.973C>T p.H325Y | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV65124347; called by muse, mutect2, varscan2
- TBRG4 | c.1322-1G>T p.X441_splice | Splice Site (SNP) | VAF 22/66 reads (33%) | catalogued as COSV51834051; called by muse, mutect2, varscan2
- TBX15 | c.1334C>T p.S445F (on ENST00000369429 / NM_001330677.2; = p.S339F on NM_152380.3) | Missense Mutation (SNP) | VAF 44/73 reads (60%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV52874811; called by muse, mutect2, varscan2
- TC2N | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.166); catalogued as COSV61747855; called by muse, mutect2, varscan2
- TCHHL1 | c.1285C>T p.L429F | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV64287031; called by muse, mutect2, varscan2
- TCTE1 | c.1091T>G p.L364R | Missense Mutation (SNP) | VAF 47/217 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65256177; called by muse, mutect2, varscan2
- TDRD5 | c.2209G>A p.D737N | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.143); catalogued as COSV54243123; called by muse, mutect2, varscan2
- TEC | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs772497479, COSV67404948; called by muse, mutect2, varscan2
- TEKT2 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 58/89 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs775279738, COSV52880634; called by muse, mutect2, varscan2
- TENM1 | c.4121C>T p.P1374L | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64439858; called by muse, mutect2, varscan2
- TENM2 | c.3508G>A p.E1170K (on ENST00000518659 / NM_001122679.2; = p.E938K on NM_001080428.3) | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1201187363, COSV69125079, COSV69133883; called by muse, varscan2
- TENM3 | c.3125G>A p.G1042E | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69300328; called by muse, mutect2, varscan2
- TEX101 | c.746C>T p.S249F (on ENST00000598265 / NM_001130011.3; = p.S267F on NM_031451.4) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as rs866575493, COSV53661601; called by muse, mutect2, varscan2
- TEX15 | c.8053G>A p.E2685K (on ENST00000256246; = p.E3068K on NM_001350162.2) | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV56351763; called by muse, mutect2, varscan2
- TFAP2A | c.257C>T p.P86L (on ENST00000482890; = p.P78L on NM_001032280.3) | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs200131527; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- THBS4 | c.295A>G p.I99V | Missense Mutation (SNP) | VAF 95/304 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs144319149; called by muse, mutect2, varscan2
- THBS4 | c.1538G>A p.G513E | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV63470218; called by muse, mutect2, varscan2
- THSD1 | c.1712C>T p.P571L | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV51630813; called by muse, mutect2, varscan2
- THSD7B | c.2003C>T p.S668L | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV55660468; called by muse, mutect2, varscan2
- TIMD4 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV50854909; called by muse, mutect2, varscan2
- TKTL1 | c.1319G>A p.G440E | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as COSV54214415; called by muse, mutect2, varscan2
- TLN2 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1014804292, COSV60888150; called by muse, mutect2, varscan2
- TLR3 | c.1526C>T p.T509I | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV57169926; called by muse, mutect2, varscan2
- TMC1 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52782768; called by muse, mutect2, varscan2
- TMC5 | c.1807G>A p.E603K (on ENST00000396229 / NM_001105248.1; = p.E357K on NM_024780.5) | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.147); catalogued as COSV54908023; called by muse, mutect2, varscan2
- TMEM74 | c.403C>T p.H135Y | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.178); catalogued as COSV52464356; called by muse, mutect2, varscan2
- TMPRSS11F | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100678459; called by muse, mutect2, varscan2
- TMPRSS4 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs778179395, COSV71109996, COSV71110875; called by muse, mutect2, varscan2
- TNFRSF10B | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.031); catalogued as COSV52393779; called by muse, mutect2, varscan2
- TNFSF15 | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as rs368084272; called by muse, mutect2, varscan2
- TNFSF9 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.684); catalogued as COSV55538877; called by muse, mutect2, varscan2
- TNIK | c.1738C>T p.R580* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV52689496; called by muse, mutect2, varscan2
- TNN | c.3805T>C p.Y1269H | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV53433011; called by muse, mutect2, varscan2
- TP63 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.146); catalogued as COSV99286663; called by muse, mutect2, varscan2
- TRAV12-3 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs370888273; called by muse, mutect2, varscan2
- TRBV2 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as rs769200737; called by muse, mutect2, varscan2
- TRHDE | c.1418G>A p.G473D | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53859742; called by muse, mutect2, varscan2
- TRPC4 | c.1887C>T p.D629= | Splice Region (SNP) | VAF 16/53 reads (30%) | catalogued as COSV59012068; called by muse, mutect2, varscan2
- TRPC4AP | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); catalogued as COSV52676493, COSV52683176; called by muse, mutect2, varscan2
- TRPM6 | c.5494C>T p.Q1832* | Nonsense Mutation (SNP) | VAF 21/62 reads (34%) | catalogued as COSV62519731; called by muse, mutect2, varscan2
- TSC1 | c.1765C>T p.P589S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.124); catalogued as rs1299279813, CD991905, COSV53766628; called by muse, mutect2, varscan2
- TSC1 | c.688C>T p.H230Y | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53771431; called by muse, mutect2, varscan2
- TSSK1B | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV66815850; called by muse, mutect2, varscan2
- TTC8 | c.1084C>A p.L362I (on ENST00000338104 / NM_001288781.1; = p.L346I on NM_144596.4) | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.351); catalogued as COSV57629521; called by muse, mutect2, varscan2
- TTF2 | c.2918C>T p.S973F | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT tolerated (0.61); PolyPhen benign (0.178); catalogued as rs1056344591, COSV65632151; called by muse, mutect2, varscan2
- TTN | c.46859G>A p.R15620Q (on ENST00000591111; = p.R8196Q on NM_003319.4) | Missense Mutation (SNP) | VAF 26/104 reads (25%) | PolyPhen benign (0.015); catalogued as rs201825412; ClinVar: likely benign / benign / uncertain significance; called by muse, mutect2, varscan2
- TTN | c.20264C>T p.P6755L (on ENST00000591111; = p.P5828L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | PolyPhen probably damaging (0.999); catalogued as COSV60261893; called by muse, mutect2, varscan2
- TTN | c.14395C>T p.R4799* (on ENST00000591111; = p.R3872* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 29/87 reads (33%) | catalogued as rs1057518470, COSV59932123; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.6248G>A p.R2083K (on ENST00000591111; = p.R2037K on NM_003319.4) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | PolyPhen benign (0.01); catalogued as CD122197, COSV60215595, COSV60261917; called by muse, mutect2, varscan2
- TTN | c.1954G>A p.E652K (on ENST00000591111; = p.E606K on NM_003319.4) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | PolyPhen benign (0.003); catalogued as rs756924799, COSV60261974; called by muse, mutect2, varscan2
- TUBA3C | c.1239G>T p.M413I | Missense Mutation (SNP) | VAF 57/177 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); catalogued as COSV68027714, COSV68029376; called by muse, mutect2, varscan2
- TUSC3 | c.308+1G>A p.X103_splice | Splice Site (SNP) | VAF 10/66 reads (15%) | catalogued as COSV65885734; called by muse, mutect2
- UGT1A4 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as COSV100529910; called by muse, mutect2, varscan2
- UGT2B10 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.443); catalogued as COSV55321422, COSV55322712; called by muse, mutect2, varscan2
- UNC5D | c.2528C>T p.P843L | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV54823789; called by muse, mutect2, varscan2
- UNC79 | c.4573C>T p.R1525W (on ENST00000393151 / NM_001346218.2; = p.R1348W on NM_020818.5) | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as rs1052514724, COSV56404196; called by muse, mutect2, varscan2
- VPS35 | c.1420C>T p.Q474* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as COSV54480545; called by muse, mutect2, varscan2
- VWA3B | c.2234C>T p.S745L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.038); catalogued as COSV68241960, COSV68247572; called by muse, mutect2, varscan2
- WDFY3 | c.7457C>T p.P2486L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV55710791; called by muse, mutect2
- WIZ | c.4213C>A p.L1405M (on ENST00000673675 / NM_001371589.1; = p.L310M on NM_021241.3) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.718); catalogued as COSV54610909; called by muse, mutect2, varscan2
- WSCD1 | c.1597C>T p.R533W | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as rs200210292, COSV58497286; called by muse, mutect2, varscan2
- WWC3 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1374321951, COSV66506087; called by muse, mutect2, varscan2
- YARS1 | c.1543G>A p.G515S | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs879254282, COSV53866980; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZBED9 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV71729204, COSV71729689; called by muse, mutect2, varscan2
- ZBTB7C | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59690243; called by muse, mutect2, varscan2
- ZFAND4 | c.1951C>T p.P651S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV60860791; called by muse, mutect2, varscan2
- ZFPM2 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.972); catalogued as rs780999906, CM152238, COSV68289941; called by muse, mutect2, varscan2
- ZFPM2 | c.3013G>A p.E1005K | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.053); catalogued as rs747521226, COSV65875280; called by muse, mutect2, varscan2
- ZFPM2 | c.3320G>T p.G1107V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.617); catalogued as COSV65875284; called by muse, mutect2, varscan2
- ZIC2 | c.1024A>C p.K342Q | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV66255453; called by muse, mutect2, varscan2
- ZIM2 | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.142); catalogued as COSV55643536; called by muse, mutect2, varscan2
- ZIM3 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs754629267, COSV54145588; called by muse, mutect2, varscan2
- ZNF207 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.844); catalogued as COSV58301431; called by muse, mutect2, varscan2
- ZNF208 | c.3643C>T p.H1215Y | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV68111049; called by muse, mutect2, varscan2
- ZNF208 | c.2390G>A p.R797K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.347); catalogued as COSV68102852, COSV68111059; called by muse, mutect2, varscan2
- ZNF354C | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV100203617; called by muse, mutect2, varscan2
- ZNF417 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.189); catalogued as COSV100364183; called by mutect2, varscan2
- ZNF443 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.034); catalogued as rs751566862, COSV56892828; called by muse, mutect2, varscan2
- ZNF613 | c.535C>T p.P179S (on ENST00000293471 / NM_001031721.4; = p.P143S on NM_024840.4) | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV53273343; called by muse, mutect2, varscan2
- ZNF804A | c.1131G>C p.E377D | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV56437757, COSV56454369, COSV56464905; called by muse, mutect2, varscan2
- ZNF831 | c.4151C>T p.S1384L | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV64043853; called by muse, mutect2, varscan2
- CSAG3 | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated, low confidence (0.44); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- GPR179 | c.5488_5498del p.K1830Pfs*6 (on ENST00000621958; = p.K1829Pfs*6 on NM_001004334.4) | Frame Shift Del (DEL) | VAF 63/151 reads (42%) | called by mutect2, pindel, varscan2
- IGHV1OR21-1 | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 30/250 reads (12%) | called by muse, mutect2, varscan2
- IGKV1-27 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- KIR2DL1 | c.790C>T p.L264F | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- MAGEF1 | c.429_442del p.Y143* | Nonsense Mutation (DEL) | VAF 13/67 reads (19%) | called by mutect2, pindel, varscan2
- PLEKHG3 | c.3373del p.Q1125Sfs*25 (on ENST00000394691; = p.Q1181Sfs*25 on NM_001308147.2) | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | called by mutect2, pindel, varscan2
- TRAV9-1 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCC12 | c.771C>T p.F257= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as COSV60917058; called by muse, mutect2, varscan2
- ABCC8 | c.2016C>T p.G672= | Silent (SNP) | VAF 64/172 reads (37%) | catalogued as rs771361396, COSV56846505; called by muse, mutect2, varscan2
- AC011448.1 | c.402C>T p.V134= | Silent (SNP) | VAF 32/115 reads (28%) | catalogued as COSV52278943; called by muse, mutect2, varscan2
- AC127029.3 | c.886C>T p.L296= | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as rs1234142824, COSV60111715; called by muse, mutect2, varscan2
- ADGRB3 | c.4479G>A p.K1493= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV53256207, COSV53259844; called by muse, mutect2, varscan2
- ADGRV1 | c.17599T>C p.L5867= | Silent (SNP) | VAF 43/131 reads (33%) | catalogued as COSV67992768; called by muse, mutect2, varscan2
- AGO1 | c.2511C>T p.P837= | Silent (SNP) | VAF 14/21 reads (67%) | catalogued as COSV100940929, COSV64596188; called by muse, mutect2, varscan2
- AGT | c.402C>T p.L134= | Silent (SNP) | VAF 42/179 reads (23%) | catalogued as rs11557885, COSV64185277; called by muse, mutect2, varscan2
- AHRR | c.222C>T p.L74= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV57091665; called by muse, mutect2, varscan2
- ALB | c.171G>A p.Q57= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV55741208; called by muse, mutect2, varscan2
- ALMS1 | c.3237C>T p.F1079= | Silent (SNP) | VAF 41/137 reads (30%) | catalogued as rs776919172, COSV52518506; called by muse, mutect2, varscan2
- ALOX15B | c.1473C>T p.I491= | Silent (SNP) | VAF 34/112 reads (30%) | catalogued as rs1009175654, COSV66479221; called by muse, mutect2, varscan2
- ALPP | c.900C>T p.I300= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV67397581; called by muse, mutect2, varscan2
- AMIGO2 | c.1503G>A p.R501= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs547623888, COSV56975238; called by muse, mutect2, varscan2
- ANKRD11 | c.597C>T p.F199= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs754679761, COSV56368620; called by muse, mutect2, varscan2
- ANPEP | c.2268C>T p.A756= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100262962; called by muse, mutect2, varscan2
- AOX1 | c.492C>T p.F164= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV65980831; called by muse, mutect2, varscan2
- ASB3 | c.1125C>T p.N375= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as rs1293987012, COSV55078881; called by muse, mutect2, varscan2
- ASXL3 | c.1873C>T p.L625= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs1183427100, COSV52475537; called by muse, mutect2
- ATP2A3 | c.735G>A p.E245= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV59233668; called by muse, mutect2
- ATP5MC2 | c.156A>T p.S52= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100100988; called by muse, mutect2, varscan2
- BCL2L12 | c.24C>T p.F8= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV55862291; called by muse, mutect2, varscan2
- BLM | c.333C>T p.F111= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV61926418; called by muse, mutect2, varscan2
- BMP5 | c.1314C>T p.V438= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV63705493; called by muse, mutect2, varscan2
- BOP1 | c.1077C>T p.F359= | Silent (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- BPIFB3 | c.288G>A p.K96= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV64957938; called by muse, mutect2
- BTBD11 | c.2283C>T p.I761= (on ENST00000280758 / NM_001018072.2; = p.I298= on NM_001017523.2) | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV55033596; called by muse, mutect2, varscan2
- BTBD11 | c.2784G>A p.L928= (on ENST00000280758 / NM_001018072.2; = p.L465= on NM_001017523.2) | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV55028688, COSV55033615; called by muse, mutect2, varscan2
- BTN1A1 | c.945C>T p.H315= | Silent (SNP) | VAF 101/254 reads (40%) | catalogued as COSV99764326; called by muse, mutect2, varscan2
- CA12 | c.867C>T p.F289= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as COSV51607427; called by muse, mutect2, varscan2
- CACNA1C | c.2748C>T p.S916= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV59756934; called by muse, mutect2, varscan2
- CACNA2D3 | c.825G>A p.A275= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as rs923437886, COSV55523133; called by muse, mutect2, varscan2
- CALML3 | c.303C>T p.V101= | Silent (SNP) | VAF 17/27 reads (63%) | catalogued as COSV59449761; called by muse, mutect2, varscan2
- CAMK4 | c.255C>T p.I85= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs201866448, COSV56662707; called by muse, mutect2, varscan2
- CAPZA3 | c.528C>T p.F176= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV56853224; called by muse, mutect2, varscan2
- CASR | c.318G>A p.K106= | Silent (SNP) | VAF 42/113 reads (37%) | catalogued as COSV56140382; called by muse, mutect2, varscan2
- CASR | c.2739G>A p.R913= (on ENST00000490131; = p.R990= on NM_000388.4) | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs200174909, COSV56134662; called by muse, mutect2, varscan2
- CBLN2 | c.670C>T p.L224= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV54050322; called by muse, mutect2, varscan2
- CCDC141 | c.3933C>T p.A1311= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs986137002, COSV55379804; called by muse, mutect2, varscan2
- CCDC24 | c.492C>T p.H164= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs771884289, COSV100530731; called by muse, mutect2, varscan2
- CCDC24 | c.493C>T p.L165= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV100530733, COSV58845196; called by muse, mutect2, varscan2
- CCDC63 | c.81G>A p.A27= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs765947594, COSV57528283; called by muse, mutect2, varscan2
- CDK1 | c.888G>A p.K296= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as rs778994173, COSV57350131; called by muse, mutect2, varscan2
- CDK5RAP3 | c.843T>C p.T281= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV58115848; called by muse, mutect2, varscan2
- CERKL | c.945G>A p.V315= (on ENST00000339098 / NM_001030311.2; = p.V289= on NM_201548.5) | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs1230628225, COSV59209746; called by muse, mutect2, varscan2
- CFAP91 | c.243C>T p.I81= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99847056; called by muse, varscan2
- CFAP91 | c.300C>T p.I100= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV56343657; called by muse, varscan2
- CGB1 | c.54A>C p.A18= | Silent (SNP) | VAF 32/117 reads (27%) | catalogued as COSV56820896; called by muse, mutect2, varscan2
- CHL1 | c.636G>A p.R212= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV56602284; called by muse, mutect2, varscan2
- CHRD | c.1096C>T p.L366= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV52611364; called by muse, mutect2, varscan2
- CHRD | c.1200G>A p.R400= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs756221362, COSV52611383; called by muse, mutect2, varscan2
- CHST3 | c.813C>T p.A271= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV64151570; called by muse, mutect2
- COL5A3 | c.3261G>A p.K1087= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as rs754117346, COSV53416996; called by muse, mutect2, varscan2
- CRAT | c.537C>T p.S179= | Silent (SNP) | VAF 94/355 reads (26%) | catalogued as COSV58878621; called by muse, mutect2, varscan2
- CRYBG1 | c.3606C>T p.S1202= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs779978674, COSV64811073; called by muse, mutect2, varscan2
- CTTNBP2 | c.513C>T p.V171= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV50449424; called by muse, mutect2, varscan2
- CX3CR1 | c.411C>T p.S137= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV64194887; called by muse, mutect2, varscan2
- CXCR4 | c.894C>T p.N298= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV54015352; called by muse, mutect2, varscan2
- CYP2B6 | c.1188C>T p.L396= | Silent (SNP) | VAF 49/160 reads (31%) | catalogued as COSV57845146; called by muse, mutect2, varscan2
- DBN1 | c.1233C>T p.P411= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs1344823392, COSV52789023; called by muse, mutect2
- DGKD | c.675C>T p.I225= (on ENST00000264057 / NM_152879.3; = p.I181= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs748145250, COSV51085455; called by muse, mutect2, varscan2
- DGKI | c.930C>T p.S310= | Silent (SNP) | VAF 28/120 reads (23%) | catalogued as COSV55968729; called by muse, mutect2, varscan2
- DNAH10 | c.4764C>T p.I1588= (on ENST00000409039; = p.I1527= on NM_207437.3) | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV68999177; called by muse, mutect2, varscan2
- DNAH5 | c.4542T>C p.F1514= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV54244745; called by muse, mutect2, varscan2
- DNAH9 | c.2067G>A p.T689= | Silent (SNP) | VAF 36/101 reads (36%) | catalogued as rs749709369, COSV52369181; called by muse, mutect2, varscan2
- DNAJC5B | c.363G>A p.T121= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as rs764610686, COSV52539238; called by muse, mutect2, varscan2
- DOK7 | c.1296G>A p.R432= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs1288310207, CD072396, COSV60773405; called by muse, mutect2, varscan2
- DYNC1H1 | c.1440C>T p.I480= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs746284696, COSV100794985, COSV64140704; called by muse, mutect2, varscan2
- EBF1 | c.633C>T p.F211= | Silent (SNP) | VAF 31/57 reads (54%) | catalogued as COSV58190369; called by muse, mutect2, varscan2
- EFCAB6 | c.1635C>T p.F545= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs866596196, COSV53060699; called by muse, mutect2, varscan2
- ELOA2 | c.1779C>T p.F593= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV55306225; called by muse, mutect2, varscan2
- EPYC | c.756C>T p.I252= | Silent (SNP) | VAF 54/196 reads (28%) | catalogued as COSV53801418; called by muse, mutect2, varscan2
- FAM234B | c.1587C>T p.F529= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV52196670; called by muse, mutect2, varscan2
- FBP1 | c.900G>A p.K300= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV64690056; called by muse, mutect2, varscan2
- FER1L6 | c.696C>T p.I232= | Silent (SNP) | VAF 74/149 reads (50%) | catalogued as rs374659858, COSV67552082; called by muse, mutect2, varscan2
- FOS | c.729C>T p.L243= | Silent (SNP) | VAF 35/98 reads (36%) | catalogued as rs1316745474, COSV57840181; called by muse, mutect2, varscan2
- FRMPD1 | c.2529G>A p.Q843= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV66699269, COSV66702106; called by muse, mutect2, varscan2
- GABRA2 | c.1092C>T p.N364= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV100734161; called by muse, mutect2, varscan2
- GABRG3 | c.1290G>A p.R430= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs1378873272, COSV61529050; called by muse, mutect2, varscan2
- GFRA3 | c.1122C>T p.N374= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV51227923; called by muse, mutect2
- GGA1 | c.396C>T p.I132= | Silent (SNP) | VAF 24/162 reads (15%) | catalogued as rs758099937, COSV100289850, COSV57331349; called by muse, mutect2, varscan2
- GLYAT | c.51C>T p.S17= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV53540107, COSV53540772; called by muse, varscan2
- GPR26 | c.774G>A p.V258= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV52935899; called by muse, mutect2
- GPRC6A | c.1014C>T p.S338= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV59951615; called by muse, mutect2, varscan2
- GPRIN3 | c.768C>T p.G256= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as rs1341100535, COSV60886135; called by muse, mutect2
- GRB7 | c.1296C>T p.F432= | Silent (SNP) | VAF 74/292 reads (25%) | catalogued as COSV58450034; called by muse, mutect2, varscan2
- GRM8 | c.1596C>T p.V532= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV100284228, COSV58856965; called by muse, mutect2, varscan2
- GRXCR1 | c.420G>A p.V140= | Silent (SNP) | VAF 47/169 reads (28%) | catalogued as COSV67673793, COSV67674267; called by muse, mutect2, varscan2
- GUCY1B1 | c.1824T>C p.N608= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV52378041; called by muse, mutect2, varscan2
- HHIPL2 | c.1533C>T p.S511= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV58566955; called by muse, mutect2, varscan2
- HLA-DQB1 | c.444C>T p.V148= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV66574052; called by muse, mutect2, varscan2
- HLA-DRA | c.399C>T p.F133= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV66623013; called by muse, mutect2, varscan2
- HOXC11 | c.507C>T p.P169= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV54533892; called by muse, mutect2, varscan2
- HSPG2 | c.3201C>T p.P1067= | Silent (SNP) | VAF 88/141 reads (62%) | catalogued as COSV65970213; called by muse, mutect2, varscan2
- IFNA21 | c.231C>T p.I77= | Silent (SNP) | VAF 44/89 reads (49%) | catalogued as COSV66518179, COSV66518646, COSV66518665; called by muse, mutect2, varscan2
- IFNA6 | c.31C>T p.L11= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as COSV66506702; called by muse, mutect2, varscan2
- IGF2BP1 | c.1728G>A p.R576= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs997617031, COSV51734635; called by muse, mutect2, varscan2
- IGHV3-20 | c.108C>T p.S36= | Silent (SNP) | VAF 40/135 reads (30%) | called by muse, mutect2, varscan2
- IGHV3-38 | c.183G>A p.G61= | Silent (SNP) | VAF 35/140 reads (25%) | called by muse, mutect2, varscan2
- IGSF9 | c.336C>T p.F112= | Silent (SNP) | VAF 42/98 reads (43%) | catalogued as COSV63640519; called by muse, mutect2, varscan2
- ISG20L2 | c.228C>T p.F76= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as COSV57461100; called by muse, mutect2, varscan2
- ITGA4 | c.1381C>T p.L461= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV52002971; called by muse, mutect2, varscan2
- ITGB3 | c.1164C>A p.L388= | Silent (SNP) | VAF 52/131 reads (40%) | catalogued as COSV101457573; called by muse, mutect2, varscan2
- KCNF1 | c.1008C>T p.F336= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs1374457615, COSV54465002; called by muse, mutect2, varscan2
- KCNH1 | c.1141C>T p.L381= (on ENST00000271751 / NM_172362.3; = p.L354= on NM_002238.4) | Silent (SNP) | VAF 36/146 reads (25%) | catalogued as COSV55083339, COSV55090366; called by muse, mutect2, varscan2
- KCNJ3 | c.1212G>A p.Q404= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as COSV54532144, COSV54542119; called by muse, mutect2, varscan2
- KCNMB4 | c.603G>A p.A201= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as rs765167113, COSV50691150; called by muse, mutect2, varscan2
- KPRP | c.582G>A p.Q194= | Silent (SNP) | VAF 77/165 reads (47%) | catalogued as COSV64222631; called by muse, mutect2, varscan2
- KRI1 | c.960C>T p.S320= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs139920982; called by muse, mutect2, varscan2
- KRT20 | c.570G>A p.L190= | Silent (SNP) | VAF 36/78 reads (46%) | catalogued as rs966116161, COSV51425833; called by muse, mutect2, varscan2
- KRT25 | c.402C>T p.F134= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as COSV56446150; called by muse, mutect2, varscan2
- LAMP5 | c.81C>T p.I27= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV55717598; called by muse, mutect2, varscan2
- LCE3E | c.141C>T p.S47= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV64232129; called by muse, mutect2, varscan2
- LILRA1 | c.1422C>T p.V474= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV52183825; called by muse, varscan2
- LILRA2 | c.108C>T p.G36= | Silent (SNP) | VAF 26/144 reads (18%) | catalogued as COSV52193526, COSV52195468; called by muse, varscan2
- LINGO4 | c.1179G>T p.G393= | Silent (SNP) | VAF 49/93 reads (53%) | catalogued as rs369003154, COSV63215953; called by muse, mutect2, varscan2
- LNPEP | c.729C>T p.I243= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as rs554423116, COSV51478129; called by muse, mutect2, varscan2
- LRP1B | c.7584C>T p.L2528= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV67259808; called by muse, mutect2, varscan2
- LRRC31 | c.870C>T p.S290= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV52982292; called by muse, mutect2, varscan2
- LRRIQ4 | c.87C>T p.F29= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs1435376210, COSV61619954; called by muse, mutect2, varscan2
- LSM14A | c.1251C>T p.F417= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV70885566; called by muse, mutect2, varscan2
- LVRN | c.2262G>A p.K754= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV63498086; called by muse, mutect2, varscan2
- MAEL | c.1290C>T p.F430= | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as rs776594071, COSV63305624, COSV63305924; called by muse, mutect2, varscan2
- MED6 | c.63C>T p.I21= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV56450894; called by muse, mutect2, varscan2
- MFSD1 | c.385C>T p.L129= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV51842582; called by muse, mutect2, varscan2
- MMP13 | c.321C>T p.F107= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV52823899; called by muse, mutect2, varscan2
- MTA3 | c.273C>G p.L91= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV68133871; called by muse, mutect2, varscan2
- MUC16 | c.12276C>T p.I4092= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs756263109, COSV67465143; called by muse, mutect2, varscan2
- MUC16 | c.9852C>T p.S3284= | Silent (SNP) | VAF 30/111 reads (27%) | catalogued as COSV67484328; called by muse, mutect2, varscan2
- MUC16 | c.8655C>T p.I2885= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV67454608; called by muse, mutect2, varscan2
- MUC16 | c.6798C>T p.F2266= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs1450797793, COSV67484339; called by muse, mutect2, varscan2
- MUC6 | c.3480C>T p.C1160= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs763367838, COSV70147860; called by muse, mutect2
- MUSK | c.1206G>A p.K402= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV51893219; called by muse, mutect2, varscan2
- MUSK | c.1357C>T p.L453= | Silent (SNP) | VAF 51/167 reads (31%) | catalogued as COSV51893234; called by muse, mutect2, varscan2
- MYCBP2 | c.11940T>C p.S3980= (on ENST00000357337; = p.S4018= on NM_015057.5) | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV62033864; called by muse, mutect2, varscan2
- MYH1 | c.471C>T p.S157= | Silent (SNP) | VAF 52/178 reads (29%) | catalogued as COSV56854811; called by muse, mutect2, varscan2
- MYH3 | c.4839C>T p.I1613= | Silent (SNP) | VAF 102/341 reads (30%) | catalogued as COSV56868684; called by muse, mutect2, varscan2
- MYO15A | c.3561C>T p.S1187= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV52762746; called by muse, mutect2, varscan2
- MYO7A | c.1296C>T p.S432= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV68686541; called by muse, mutect2, varscan2
- NANOG | c.573G>A p.G191= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs1164650565, COSV57552301; called by muse, mutect2, varscan2
- NDN | c.864G>A p.Q288= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV59360517; called by muse, mutect2
- NLRC5 | c.3558C>T p.T1186= | Silent (SNP) | VAF 66/242 reads (27%) | catalogued as COSV52660843; called by muse, mutect2, varscan2
- NLRP2 | c.1686C>T p.N562= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs1259045887, COSV54758945; called by muse, mutect2
- NLRP4 | c.2088G>A p.L696= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as COSV56708298; called by muse, mutect2, varscan2
- NLRP8 | c.465G>A p.S155= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as rs1044542565, COSV52592119; called by muse, mutect2, varscan2
- NOS3 | c.165G>A p.P55= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs1184486784, COSV52494114; called by muse, mutect2, varscan2
- NOTCH4 | c.2661G>A p.Q887= | Silent (SNP) | VAF 22/127 reads (17%) | catalogued as rs755584219, COSV66682976; called by muse, mutect2, varscan2
- NPTXR | c.1104C>T p.A368= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV60729262; called by muse, mutect2, varscan2
- NSD1 | c.5559G>A p.E1853= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as COSV61781955, COSV61784744; called by muse, mutect2, varscan2
- NTN5 | c.1056G>A p.S352= | Silent (SNP) | VAF 35/146 reads (24%) | catalogued as rs760107980, COSV54308344; called by muse, mutect2, varscan2
- OR10A7 | c.570G>A p.V190= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as rs1486255574, COSV58277858; called by muse, mutect2, varscan2
- OR10H4 | c.96C>T p.Y32= | Silent (SNP) | VAF 63/232 reads (27%) | catalogued as COSV59062630; called by muse, mutect2, varscan2
- OR10J3 | c.138C>T p.I46= | Silent (SNP) | VAF 46/202 reads (23%) | catalogued as COSV59953920, COSV59955339; called by muse, mutect2, varscan2
- OR10Q1 | c.568C>T p.L190= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV57471518; called by muse, mutect2
- OR13C4 | c.531C>T p.F177= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV52928020; called by muse, mutect2, varscan2
- OR1D5 | c.549C>T p.I183= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV73859613; called by muse, mutect2, varscan2
- OR1G1 | c.789C>T p.P263= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV61030494; called by muse, mutect2
- OR1K1 | c.177C>T p.P59= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV52957118; called by muse, mutect2, varscan2
- OR1L4 | c.183C>T p.Y61= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV52339798; called by muse, mutect2, varscan2
- OR2B3 | c.579G>A p.K193= | Silent (SNP) | VAF 38/76 reads (50%) | catalogued as COSV65851020; called by muse, mutect2, varscan2
- OR2B3 | c.357C>T p.S119= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV65851136; called by muse, mutect2, varscan2
- OR2F1 | c.621G>T p.L207= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV67331883; called by muse, mutect2, varscan2
- OR2S2 | c.705G>A p.R235= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as COSV59530906; called by muse, mutect2, varscan2
- OR4A16 | c.634C>T p.L212= | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as COSV59044644; called by muse, mutect2, varscan2
- OR4B1 | c.216C>T p.S72= | Silent (SNP) | VAF 39/140 reads (28%) | catalogued as COSV58883642; called by muse, mutect2, varscan2
- OR4D9 | c.753C>T p.F251= | Silent (SNP) | VAF 89/260 reads (34%) | catalogued as rs771977144, COSV61434214; called by muse, varscan2
- OR52E2 | c.471C>T p.F157= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs139722116, COSV58612502; called by muse, mutect2, varscan2
- OR52K1 | c.147C>T p.F49= | Silent (SNP) | VAF 34/117 reads (29%) | catalogued as rs1157063698, COSV56904454; called by muse, mutect2, varscan2
- OR5A2 | c.750C>T p.T250= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV57391665; called by muse, mutect2, varscan2
- OR5B17 | c.873G>A p.R291= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV62160063; called by muse, mutect2, varscan2
- OR5H2 | c.645C>T p.T215= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV62351579; called by muse, mutect2, varscan2
- OR6C70 | c.786G>A p.A262= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs776105671, COSV59245280; called by muse, mutect2, varscan2
- OR6Y1 | c.825C>T p.S275= | Silent (SNP) | VAF 28/156 reads (18%) | catalogued as COSV56930948; called by muse, mutect2, varscan2
- OR8D1 | c.255C>T p.F85= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV63441709; called by muse, mutect2, varscan2
- OR8D2 | c.40C>T p.L14= | Silent (SNP) | VAF 31/106 reads (29%) | catalogued as rs1053243161, COSV62488895; called by muse, mutect2, varscan2
- OTOGL | c.3807A>G p.L1269= (on ENST00000547103; = p.L1260= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV72007249; called by muse, mutect2, varscan2
- P2RY8 | c.618C>T p.F206= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs1375126755, COSV67177366; called by muse, mutect2, varscan2
- P3H2 | c.1356C>T p.F452= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs267599731, COSV60021707; called by muse, mutect2, varscan2
- PAPPA2 | c.3204G>A p.V1068= | Silent (SNP) | VAF 42/206 reads (20%) | catalogued as COSV62805123, COSV62807842; called by muse, mutect2, varscan2
- PARD3B | c.1554C>T p.S518= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV62525153; called by muse, mutect2, varscan2
- PCDHB12 | c.1041C>T p.I347= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs1430889554, COSV53399722; called by muse, mutect2, varscan2
- PCDHGA11 | c.702C>T p.L234= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV53978747; called by muse, mutect2, varscan2
- PCED1B | c.246C>T p.F82= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV71395558; called by muse, mutect2, varscan2
- PCSK5 | c.237G>A p.T79= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as rs200413560, COSV65087490; called by muse, mutect2, varscan2
- PGC | c.66C>T p.P22= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV63123570; called by muse, mutect2, varscan2
- PHYHD1 | c.276C>T p.F92= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as COSV58282119; called by muse, mutect2, varscan2
- PLA2G3 | c.930G>A p.K310= | Silent (SNP) | VAF 78/221 reads (35%) | catalogued as COSV53211923; called by muse, mutect2, varscan2
- PLCB4 | c.117C>T p.F39= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV53803439; called by muse, mutect2, varscan2
- PLEKHG3 | c.2982C>T p.V994= (on ENST00000394691; = p.V1050= on NM_001308147.2) | Silent (SNP) | VAF 38/147 reads (26%) | catalogued as COSV55982702; called by muse, mutect2, varscan2
- POTEF | c.1932C>T p.I644= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV62543319; called by muse, mutect2, varscan2
104 further variants in this file (0 protein-altering or splice-affecting, 81 silent, 23 other) are not listed here.
